Gene-level copy-number profile of tumor specimen TCGA-JY-A93E-01A from TCGA case TCGA-JY-A93E, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,427 days).
Specimen TCGA-JY-A93E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.bbc43c34-1bae-41ea-96d8-31046f61fc93.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A93E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6309701a-70c4-48fb-a858-bd282c404a74

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,185; copy number 2: 24,607; copy number 3: 27,043; copy number 4: 3,446; copy number 5: 370; copy number 6: 1,564; copy number 7: 750; copy number 8: 131; copy number 9: 24; copy number 10: 38; copy number 11: 164; copy number 12: 207; copy number 13: 189; copy number 14: 7; copy number 16: 12; copy number 18: 46; copy number 19: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A93E-01A-11D-A37B-01): tumor purity 0.46, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,603 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 1 gene, copy number 10 (within-gene range 2–10): AC058822.1.
- chr4:53,899,871–55,125,595, 25 genes, copy number 8–10: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr7:92,112,159–100,723,700, 235 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:109,322,320–118,951,259, 118 genes, copy number 9–12 (broad region; genes not listed).
- chr8:11,486,894–12,388,296, 46 genes, copy number 18 (within-gene range 3–18): BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.4, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1.
- chr8:13,909,231–15,238,431, 4 genes, copy number 10–11 (within-gene range 2–19): AC022690.1, AC023538.1, SGCZ, AC022039.1.
- chr8:14,487,776–14,879,819, 4 genes, copy number 10–19: RNU6-397P, AC040926.1, MIR383, AC084838.1.
- chr8:46,028,804–46,028,892, 1 gene, copy number 14: AC118650.1.
- chr11:26,188,842–26,663,289, 1 gene, copy number 11 (within-gene range 2–11): ANO3.
- chr11:26,285,578–34,663,288, 129 genes, copy number 11–12 (within-gene range 3–12) (broad region; genes not listed).
- chr11:67,991,100–74,254,703, 207 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:78,652,829–79,441,030, 1 gene, copy number 10 (within-gene range 4–10): TENM4.
- chr11:79,092,848–81,556,425, 16 genes, copy number 10–14: AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:98,565,074–106,469,296, 105 genes, copy number 7–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
